Somatic mutation profile of tumor specimen MMRF_2324_1_BM_CD138pos (aliquot MMRF_2324_1_BM_CD138pos_T3_KHS5U_K14013) from MMRF case MMRF_2324, project MMRF-COMMPASS (Multiple Myeloma CoMMpass Study). Sex at birth: male; Vital status: Alive; Primary diagnosis: Multiple myeloma; Tissue or organ of origin: Bone marrow; Age at diagnosis: 66.5 years (24,277 days).
Specimen MMRF_2324_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 4099a49f-ac3e-47bc-b6a1-26f60483c616.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MMRF_2324_1_PB_Whole (Blood Derived Normal), aliquot MMRF_2324_1_PB_Whole_C3_KHS5U_K14012; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/6f2a3803-af07-4b25-91ed-a3b96edc1880

The open-access MAF lists 119 somatic variants for this specimen: 57 protein-altering or splice-affecting, 12 silent, 50 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, 3'UTR 28, Intron 13, Silent 12, Nonsense Mutation 6, 5'UTR 5, Splice Site 4, RNA 2, Frame Shift Ins 2, 5'Flank 2, Frame Shift Del 2, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 67/198 reads (34%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- ACAD10 | c.1936C>T p.H646Y | Missense Mutation (SNP) | VAF 63/152 reads (41%) | SIFT tolerated (1); PolyPhen benign (0.023); catalogued as COSV58155893; called by muse, mutect2, varscan2
- CCR6 | c.464G>A p.R155Q | Missense Mutation (SNP) | VAF 10/89 reads (11%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.764); catalogued as rs766902152; called by muse, mutect2, varscan2
- CMIP | c.1090G>A p.D364N (on ENST00000537098 / NM_198390.2; = p.D270N on NM_030629.3) | Missense Mutation (SNP) | VAF 69/122 reads (57%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.335); catalogued as rs1459094158, COSV67697598; called by muse, mutect2, varscan2
- CSTF1 | c.1055G>A p.R352H | Missense Mutation (SNP) | VAF 62/162 reads (38%) | SIFT tolerated (0.11); PolyPhen benign (0); catalogued as rs1168730288, COSV53860454; called by muse, mutect2, varscan2
- DNAH10 | c.10216C>T p.R3406C (on ENST00000409039; = p.R3345C on NM_207437.3) | Missense Mutation (SNP) | VAF 26/125 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); catalogued as rs769678271; called by muse, mutect2, varscan2
- FAT4 | c.1256T>G p.L419R | Missense Mutation (SNP) | VAF 67/180 reads (37%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV67902723; called by muse, mutect2, varscan2
- IGHV2-70 | c.53T>G p.L18* | Nonsense Mutation (SNP) | VAF 30/64 reads (47%) | catalogued as rs546731210; called by muse, varscan2
- IGLV3-1 | c.41G>A p.C14Y | Missense Mutation (SNP) | VAF 72/102 reads (71%) | SIFT tolerated (0.06); PolyPhen benign (0.109); catalogued as rs1315687985; called by muse, mutect2, varscan2
- INO80 | c.1283A>G p.D428G | Missense Mutation (SNP) | VAF 56/127 reads (44%) | SIFT tolerated (0.5); PolyPhen benign (0.227); catalogued as rs1398581277; called by muse, mutect2, varscan2
- LMTK2 | c.1502C>T p.T501M | Missense Mutation (SNP) | VAF 112/353 reads (32%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.776); catalogued as rs201350910; called by muse, mutect2, varscan2
- NYAP1 | c.497G>A p.R166Q | Missense Mutation (SNP) | VAF 37/184 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as rs745610540, COSV55717140; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.1532A>G p.N511S (on ENST00000259318 / NM_001136562.3; = p.N742S on NM_007203.5) | Missense Mutation (SNP) | VAF 48/212 reads (23%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as rs376250463; called by muse, mutect2, varscan2
- PCED1A | c.355G>T p.E119* | Nonsense Mutation (SNP) | VAF 55/142 reads (39%) | catalogued as COSV62313482; called by muse, mutect2, varscan2
- PCLO | c.8526G>C p.Q2842H | Missense Mutation (SNP) | VAF 33/135 reads (24%) | SIFT deleterious (0.02); PolyPhen benign (0.015); catalogued as rs766103930; called by muse, mutect2, varscan2
- PTPRD | c.91G>A p.V31I | Missense Mutation (SNP) | VAF 93/203 reads (46%) | SIFT tolerated (0.12); PolyPhen benign (0.054); catalogued as rs146973770; called by muse, mutect2, varscan2
- RASD2 | c.331C>T p.R111C | Missense Mutation (SNP) | VAF 33/183 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs1187775929; called by muse, mutect2, varscan2
- REEP6 | c.517G>A p.V173I | Missense Mutation (SNP) | VAF 84/328 reads (26%) | SIFT tolerated (0.13); PolyPhen benign (0.048); catalogued as COSV52015028, COSV99278525; called by muse, mutect2, varscan2
- SERPINA5 | c.1116C>G p.F372L | Missense Mutation (SNP) | VAF 26/157 reads (17%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as COSV100291682; called by muse, mutect2, varscan2
- SULT1C2 | c.183G>A p.M61I | Missense Mutation (SNP) | VAF 42/115 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.232); catalogued as COSV52264528; called by muse, varscan2
- TENT5C | c.208C>T p.R70W | Missense Mutation (SNP) | VAF 66/134 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as rs1432369724, COSV65615989; called by muse, mutect2
- WT1 | c.805C>T p.P269S | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.947); catalogued as COSV60085439; called by muse, mutect2, varscan2
- ZNF534 | c.341G>A p.G114E (on ENST00000332323 / NM_001143939.3; = p.G101E on NM_001143938.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT tolerated (0.11); PolyPhen benign (0.052); catalogued as rs867947117; called by muse, mutect2, varscan2
- ACOT7 | c.861C>T p.G287= (on ENST00000377855 / NM_181864.3; = p.G277= on NM_007274.4) | Splice Region (SNP) | VAF 49/135 reads (36%) | called by muse, mutect2, varscan2
- ANGEL1 | c.1373C>T p.A458V | Missense Mutation (SNP) | VAF 10/29 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ARMH2 | c.288T>A p.F96L | Missense Mutation (SNP) | VAF 68/208 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- BNC1 | c.292C>T p.L98F | Missense Mutation (SNP) | VAF 7/141 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CBLB | c.1697dup p.P567Tfs*4 | Frame Shift Ins (INS) | VAF 37/101 reads (37%) | called by mutect2, pindel, varscan2
- CLCN3 | c.1151C>T p.P384L | Missense Mutation (SNP) | VAF 56/136 reads (41%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.574); called by muse, mutect2, varscan2
- CTTNBP2 | c.2024C>T p.S675F | Missense Mutation (SNP) | VAF 67/230 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.613); called by muse, mutect2, varscan2
- DDX42 | c.13A>G p.K5E | Missense Mutation (SNP) | VAF 21/143 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- DGKB | c.830-2A>C p.X277_splice | Splice Site (SNP) | VAF 19/73 reads (26%) | called by muse, mutect2, varscan2
- DNAJC3 | c.806A>T p.N269I | Missense Mutation (SNP) | VAF 32/65 reads (49%) | SIFT tolerated (0.1); PolyPhen benign (0.294); called by muse, mutect2, varscan2
- FOXO1 | c.398A>G p.Q133R | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (0.38); PolyPhen benign (0.025); called by muse, mutect2, varscan2
- GPR158 | c.148G>A p.G50S | Missense Mutation (SNP) | VAF 35/92 reads (38%) | SIFT tolerated, low confidence (0.47); PolyPhen benign (0); called by muse, mutect2, varscan2
- IDH3G | c.1107_1110dup p.T371Gfs*5 | Frame Shift Ins (INS) | VAF 54/80 reads (68%) | called by mutect2, pindel, varscan2
- IGHV2-70 | c.97_115delinsGTCAGAGAGACCCTCATAT p.P33_T38delinsVRETLI | Missense Mutation (ONP) | VAF 3/22 reads (14%) | called by pindel, varscan2*
- IGHV2-70D | c.53T>A p.L18* | Nonsense Mutation (SNP) | VAF 38/48 reads (79%) | called by muse, varscan2
- KMT2A | c.9425_9470del p.S3142Ffs*55 | Frame Shift Del (DEL) | VAF 56/286 reads (20%) | called by mutect2, pindel
- LRP6 | c.647+1G>A p.X216_splice | Splice Site (SNP) | VAF 11/96 reads (11%) | called by muse, mutect2, varscan2
- MAPK8 | c.974A>T p.Y325F | Missense Mutation (SNP) | VAF 49/134 reads (37%) | SIFT tolerated (0.32); PolyPhen benign (0.047); called by muse, mutect2, varscan2
- MUC16 | c.21478G>A p.D7160N | Missense Mutation (SNP) | VAF 50/158 reads (32%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PA2G4 | c.482A>C p.N161T | Missense Mutation (SNP) | VAF 6/156 reads (4%) | SIFT tolerated (0.29); PolyPhen benign (0.054); called by muse, mutect2
- PCDH17 | c.3001T>C p.F1001L | Missense Mutation (SNP) | VAF 48/180 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- RBM19 | c.649A>T p.K217* | Nonsense Mutation (SNP) | VAF 11/200 reads (6%) | called by muse, mutect2
- ROS1 | c.6136-3_6139del p.X2046_splice | Splice Site (DEL) | VAF 32/197 reads (16%) | called by mutect2, varscan2
- RPGRIP1 | c.607A>T p.I203L | Missense Mutation (SNP) | VAF 24/61 reads (39%) | SIFT tolerated (0.55); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SOX1 | c.1030A>T p.I344F | Missense Mutation (SNP) | VAF 3/19 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.178); called by muse, mutect2
- SPTB | c.3680C>T p.P1227L | Missense Mutation (SNP) | VAF 38/209 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- SZT2 | c.8162C>T p.P2721L (on ENST00000634258 / NM_001365999.1; = p.P2664L on NM_015284.4) | Missense Mutation (SNP) | VAF 38/113 reads (34%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- TBRG1 | c.655A>G p.T219A | Missense Mutation (SNP) | VAF 57/179 reads (32%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.847); called by muse, mutect2, varscan2
- TTC39B | c.217C>T p.R73* | Nonsense Mutation (SNP) | VAF 34/350 reads (10%) | called by muse, mutect2
- UBE2I | c.431A>C p.Y144S | Missense Mutation (SNP) | VAF 68/205 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- USP41 | c.829del p.Q277Rfs*11 | Frame Shift Del (DEL) | VAF 27/151 reads (18%) | called by mutect2, pindel, varscan2
- VCAN | c.1042+3_1042+6del p.X348_splice | Splice Site (DEL) | VAF 55/220 reads (25%) | called by mutect2, pindel, varscan2
- ZNF442 | c.358G>A p.V120M | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT tolerated (0.17); PolyPhen benign (0.012); called by muse, mutect2
- ZNF732 | c.189C>A p.Y63* | Nonsense Mutation (SNP) | VAF 11/34 reads (32%) | called by muse, mutect2, varscan2
- AHR | c.615A>C p.P205= | Silent (SNP) | VAF 13/142 reads (9%) | called by muse, mutect2
- B4GALNT4 | c.1983G>A p.S661= | Silent (SNP) | VAF 4/47 reads (9%) | catalogued as rs1025551587; called by muse, mutect2
- CACNA1H | c.2892C>T p.I964= | Silent (SNP) | VAF 53/122 reads (43%) | catalogued as rs769118582; called by muse, mutect2, varscan2
- CHGB | c.921C>T p.P307= | Silent (SNP) | VAF 42/118 reads (36%) | catalogued as rs370757045; called by muse, mutect2, varscan2
- FAM110A | c.786G>A p.E262= | Silent (SNP) | VAF 54/119 reads (45%) | called by muse, mutect2, varscan2
- IGLV3-22 | c.219C>T p.Y73= | Silent (SNP) | VAF 105/242 reads (43%) | catalogued as rs552865385; called by muse, mutect2, varscan2
- PDHX | c.834C>A p.I278= | Silent (SNP) | VAF 47/204 reads (23%) | called by muse, mutect2, varscan2
- PLAGL1 | c.9G>A p.T3= | Silent (SNP) | VAF 20/46 reads (43%) | catalogued as rs539999694, COSV61334159; called by muse, mutect2, varscan2
- S1PR5 | c.1146C>T p.P382= | Silent (SNP) | VAF 16/29 reads (55%) | catalogued as rs761762706; called by muse, mutect2, varscan2
- TG | c.7320C>T p.V2440= | Silent (SNP) | VAF 12/47 reads (26%) | called by muse, mutect2, varscan2
- TRABD2B | c.939G>A p.A313= | Silent (SNP) | VAF 73/199 reads (37%) | catalogued as rs1015804168; called by muse, mutect2, varscan2
- TSC1 | c.2484C>T p.L828= | Silent (SNP) | VAF 14/308 reads (5%) | called by muse, mutect2
- ABCC6 | c.219+19A>C | Intron (SNP) | VAF 53/129 reads (41%) | called by muse, mutect2, varscan2
- AC004947.2 | chr7:26533895 C>T | 5'Flank (SNP) | VAF 27/99 reads (27%) | called by muse, mutect2, varscan2
- ACVRL1 | c.*625A>C | 3'UTR (SNP) | VAF 29/82 reads (35%) | called by muse, mutect2, varscan2
- ATG12 | c.*277G>A | 3'UTR (SNP) | VAF 5/67 reads (7%) | called by muse, mutect2
- BCL7A | chr12:122021524 G>A | 5'Flank (SNP) | VAF 44/103 reads (43%) | catalogued as rs529209092, COSV55848044; called by muse, mutect2, varscan2
- BIRC2 | c.-858T>A | 5'UTR (SNP) | VAF 41/158 reads (26%) | called by muse, mutect2, varscan2
- BOD1 | c.*56A>G | 3'UTR (SNP) | VAF 15/276 reads (5%) | called by muse, mutect2
- C2orf91 | n.2594G>A | RNA (SNP) | VAF 7/96 reads (7%) | called by muse, mutect2
- CALN1 | c.*360A>G | 3'UTR (SNP) | VAF 38/180 reads (21%) | called by muse, mutect2, varscan2
- CDC37L1 | c.*1323C>T | 3'UTR (SNP) | VAF 62/124 reads (50%) | catalogued as rs944073776; called by muse, mutect2, varscan2
- CENPH | c.-16T>C | 5'UTR (SNP) | VAF 11/30 reads (37%) | called by muse, mutect2, varscan2
- CENPH | c.-15T>A | 5'UTR (SNP) | VAF 10/29 reads (34%) | called by muse, mutect2, varscan2
- CFAP46 | c.7584-102T>C | Intron (SNP) | VAF 23/56 reads (41%) | called by muse, mutect2, varscan2
- CHD1 | c.*99C>T | 3'UTR (SNP) | VAF 62/170 reads (36%) | called by muse, mutect2, varscan2
- CUX1 | c.31-2848G>A | Intron (SNP) | VAF 19/143 reads (13%) | called by muse, mutect2, varscan2
- FAM3D | c.586-24T>A | Intron (SNP) | VAF 63/146 reads (43%) | called by muse, mutect2, varscan2
- FMOD | c.*1342C>A | 3'UTR (SNP) | VAF 40/79 reads (51%) | called by muse, mutect2, varscan2
- FRMPD4 | c.*81C>T | 3'UTR (SNP) | VAF 97/121 reads (80%) | called by muse, mutect2, varscan2
- GAPDH | c.29+133C>T | Intron (SNP) | VAF 34/90 reads (38%) | called by muse, mutect2, varscan2
- GLRX5 | c.*239G>A | 3'UTR (SNP) | VAF 3/49 reads (6%) | catalogued as rs893393201; called by muse, mutect2
- GNAQ | c.*4854T>C | 3'UTR (SNP) | VAF 40/81 reads (49%) | called by muse, mutect2, varscan2
- GPR153 | c.*1406G>A | 3'UTR (SNP) | VAF 66/146 reads (45%) | called by muse, mutect2, varscan2
- HEPHL1 | c.*521G>C | 3'UTR (SNP) | VAF 13/50 reads (26%) | called by muse, mutect2, varscan2
- ING5 | c.*351G>A | 3'UTR (SNP) | VAF 79/182 reads (43%) | called by muse, mutect2, varscan2
- IRF4 | c.*1835dup | 3'UTR (INS) | VAF 30/115 reads (26%) | called by mutect2, pindel, varscan2
- LINC02118 | n.218C>T | RNA (SNP) | VAF 47/169 reads (28%) | called by muse, mutect2, varscan2
- LIX1L | c.*240T>C | 3'UTR (SNP) | VAF 18/78 reads (23%) | catalogued as rs1484544914; called by muse, mutect2, varscan2
- LOX | c.*1673C>T | 3'UTR (SNP) | VAF 24/67 reads (36%) | called by muse, mutect2, varscan2
- MAGED1 | c.1486+27G>A | Intron (SNP) | VAF 4/59 reads (7%) | catalogued as rs1557364434; called by muse, mutect2
- MAPK8 | c.872-10A>G | Intron (SNP) | VAF 26/75 reads (35%) | called by muse, mutect2, varscan2
- MAPK8 | c.*1745G>T | 3'UTR (SNP) | VAF 45/129 reads (35%) | called by muse, mutect2, varscan2
- MMADHC | c.-53+179A>C | Intron (SNP) | VAF 26/74 reads (35%) | called by muse, mutect2, varscan2
- NEB | c.8890-2844C>A | Intron (SNP) | VAF 22/84 reads (26%) | called by muse, mutect2, varscan2
- ONECUT2 | c.*14182A>G | 3'UTR (SNP) | VAF 77/301 reads (26%) | called by muse, mutect2, varscan2
- OPRM1 | c.*216C>T | 3'UTR (SNP) | VAF 28/68 reads (41%) | catalogued as rs915525700; called by muse, mutect2, varscan2
- PAQR3 | c.*5+267C>G | Intron (SNP) | VAF 9/32 reads (28%) | called by muse, mutect2, varscan2
- PGBD4 | c.-439G>T | 5'UTR (SNP) | VAF 36/94 reads (38%) | called by muse, mutect2, varscan2
- SCN3B | c.-25-123G>A | Intron (SNP) | VAF 15/120 reads (13%) | catalogued as rs1392607783; called by muse, mutect2, varscan2
- SLC4A1 | c.*2067G>A | 3'UTR (SNP) | VAF 10/27 reads (37%) | catalogued as rs533644288; called by muse, mutect2, varscan2
- STON1 | c.*2618C>T | 3'UTR (SNP) | VAF 9/50 reads (18%) | called by muse, mutect2, varscan2
- TGFBR1 | c.*1634A>C | 3'UTR (SNP) | VAF 45/121 reads (37%) | called by muse, mutect2, varscan2
- TIGIT | c.*222del | 3'UTR (DEL) | VAF 9/28 reads (32%) | called by mutect2, pindel, varscan2
- TMEM131 | c.*68T>G | 3'UTR (SNP) | VAF 62/163 reads (38%) | called by muse, mutect2, varscan2
- TMEM86A | c.*996A>G | 3'UTR (SNP) | VAF 20/102 reads (20%) | called by muse, mutect2, varscan2
- UBE2Q2 | c.*341T>C | 3'UTR (SNP) | VAF 21/62 reads (34%) | called by muse, mutect2, varscan2
- UMAD1 | c.*19C>T | 3'UTR (SNP) | VAF 104/417 reads (25%) | catalogued as rs575046717; called by muse, mutect2, varscan2
- UNC50 | c.-4-334G>A | Intron (SNP) | VAF 18/55 reads (33%) | called by muse, mutect2, varscan2
- WDR91 | c.*992G>C | 3'UTR (SNP) | VAF 35/130 reads (27%) | called by muse, mutect2, varscan2
- ZFYVE28 | c.701+4832G>A | Intron (SNP) | VAF 17/47 reads (36%) | catalogued as rs754497373; called by muse, mutect2, varscan2
- ZNHIT6 | c.-50C>T | 5'UTR (SNP) | VAF 59/156 reads (38%) | called by muse, mutect2, varscan2
